Gene-level copy-number profile of tumor specimen TARGET-40-0A4I42-01A from TARGET case TARGET-40-0A4I42, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 17.2 years (6,268 days).
Specimen TARGET-40-0A4I42-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.9d4ced21-c3f5-56bb-9f9d-0a8b5c11503d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I42-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/870d7c65-a696-47b3-903e-ddb164999afa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 13; copy number 2: 676; copy number 3: 15,168; copy number 4: 7,124; copy number 5: 12,327; copy number 6: 8,969; copy number 7: 9,799; copy number 8: 3,310; copy number 9: 930; copy number 10: 283; copy number 11: 302; copy number 12: 19; copy number 13: 164; copy number 14: 88; copy number 15: 31; copy number 16: 43; copy number 17: 4; copy number 19: 46; copy number 20: 9; copy number 21: 69; copy number 22: 8; copy number 23: 77; copy number 24: 7; copy number 25: 30; copy number 28: 23; copy number 29: 73; copy number 30: 7; copy number 31: 60; copy number 35: 3; copy number 37: 5; copy number 39: 26; copy number 89: 25.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,734,602–241,768,816, 1 gene (within-gene range 0–2): D2HGDH.
- chr2:241,776,822–242,160,153, 18 genes: GAL3ST2, AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5, LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr10:81,870,778–81,875,133, 1 gene: AL096706.1.
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–3): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene (within-gene range 0–3): AC139100.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 13,171 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,870,945–17,827,063, 25 genes, copy number 8: BX284668.2, RNU1-5P, BX284668.5, BX284668.4, RNU1-2, BX284668.6, MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3, SDHB, PADI2, LINC02783, AL590644.2, PADI1, PADI3, MIR3972, PADI4, PADI6, RCC2-AS1, RCC2, ARHGEF10L, LINC02810, ACTL8.
- chr1:21,950,679–23,369,836, 47 genes, copy number 13 (within-gene range 4–13): AL590556.2, CELA3B, AL590556.3, RN7SL386P, RNU6-1022P, CELA3A, RN7SL186P, RNU6-776P, LINC01635, LINC00339, CDC42, CDC42-AS1, AL031281.1, CDC42-IT1, MPHOSPH6P1, WNT4, AL445253.1, MIR4418, PPIAP34, AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1, TEX46, KDM1A, AL031428.1, MIR3115, AL031428.2, LUZP1, AL161672.1, RNU6-514P, RNU6-135P, HTR1D, AL109936.1, LINC01355, AL109936.9, HNRNPR, ZNF436.
- chr1:36,329,630–46,543,969, 341 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr1:52,602,371–71,047,808, 331 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:71,048,855–121,580,524, 880 genes, copy number 7 (broad region; genes not listed).
- chr1:147,079,746–151,348,027, 190 genes, copy number 10 (broad region; genes not listed).
- chr1:152,656,332–205,684,307, 1,276 genes, copy number 7–11 (broad region; genes not listed).
- chr1:214,051,194–233,730,746, 393 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:8,501,807–9,880,255, 35 genes, copy number 7 (within-gene range 3–7): LMCD1, AC034187.1, SSUH2, OR7E122P, CAV3, OXTR, RAD18, AC034186.2, AC034186.1, SRGAP3, SRGAP3-AS1, AC037193.1, SRGAP3-AS2, SRGAP3-AS3, SRGAP3-AS4, AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC.
- chr5:37,379,285–54,878,588, 195 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr5:105,922,994–174,850,725, 1,199 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr6:36,697,826–50,857,662, 302 genes, copy number 7–37 (within-gene range 3–37) (broad region; genes not listed).
- chr8:150,584–131,317,632, 2,195 genes, copy number 7 (broad region; genes not listed).
- chr11:47,617,315–57,390,650, 238 genes, copy number 7 (broad region; genes not listed).
- chr11:78,139,771–110,464,884, 500 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:47,782,722–48,442,411, 41 genes, copy number 14–15 (within-gene range 4–15): HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2, RNU6-1203P, AC004801.1, PFKM, MIR6505, ASB8, AC074029.3, AC074029.2, PHBP18, AC074029.1, CCDC184, AC074029.4, AC024257.3, OR10AD1, AC024257.1, AC024257.5, H1-7, AC024257.2, ZNF641, AC090115.1, OR5BK1P, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P.
- chr12:52,263,948–53,064,379, 50 genes, copy number 21 (within-gene range 5–21): AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2.
- chr12:54,337,216–55,414,787, 42 genes, copy number 14–25: MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5, MUCL1, TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1.
- chr12:57,253,762–60,363,935, 77 genes, copy number 8–31 (within-gene range 4–31) (broad region; genes not listed).
- chr12:69,584,722–90,100,763, 244 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr13:50,812,988–109,401,641, 630 genes, copy number 7–14 (within-gene range 6–14) (broad region; genes not listed).
- chr14:18,333,726–19,957,996, 83 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr14:21,200,079–30,373,115, 352 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr14:48,394,815–50,561,126, 54 genes, copy number 13–25 (within-gene range 5–25): AL358335.2, AL358335.1, RPL18P1, AL512360.1, AL110505.1, ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2.
- chr14:59,135,488–60,982,585, 40 genes, copy number 10–11: AKR1B1P5, PPIAP5, DAAM1, GPR135, L3HYPDH, AL121694.1, JKAMP, CCDC175, RTN1, MIR5586, AL133299.1, LRRC9, AL157911.1, PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322, C14orf39, RBM8B, GNRHR2P1, SALL4P7, SIX6, AL049874.3, AL049874.4, AL049874.2, AL049874.1, SALRNA1, SIX1, SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P.
- chr14:102,080,742–106,875,071, 329 genes, copy number 11–23 (within-gene range 5–23) (broad region; genes not listed).
- chr15:69,160,584–70,198,509, 20 genes, copy number 8: GLCE, AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2, DRAIC, AC100826.1, GEMIN8P1, AC021818.1, TLE3, MIR629, RNU6-745P, AC026583.1.
- chr15:74,429,445–76,059,795, 84 genes, copy number 8 (broad region; genes not listed).
- chr15:76,931,738–77,963,654, 26 genes, copy number 8: RCN2, RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1, AC046168.1, AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1, CSPG4P13, AC104758.2, AC104758.3, RN7SL214P, COMMD4P1, AC104758.4.
- chr15:78,437,431–81,755,217, 94 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr15:82,531,653–101,933,350, 477 genes, copy number 7–89 (broad region; genes not listed).
- chr16:24,098,239–26,729,126, 43 genes, copy number 7: AC130448.1, MIR1273H, AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16, AC009158.1, AC130464.1, AC002331.1, LINC02195, AC009035.1.
- chr16:46,469,341–66,552,544, 407 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr16:77,104,260–82,575,518, 109 genes, copy number 7–8 (broad region; genes not listed).
- chr17:7,705,202–13,018,065, 146 genes, copy number 7–39 (broad region; genes not listed).
- chr18:22,647,582–23,672,748, 20 genes, copy number 8: RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.
- chr19:27,638,483–33,521,791, 128 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:28,563,850–63,627,101, 870 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr22:16,405,330–19,667,555, 160 genes, copy number 8 (broad region; genes not listed).
- chr22:34,589,085–45,845,307, 389 genes, copy number 8–16 (within-gene range 5–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
